Somatic mutation profile of tumor specimen TCGA-EJ-7786-01A (aliquot TCGA-EJ-7786-01A-11D-2114-08) from TCGA case TCGA-EJ-7786, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.4 years (22,793 days).
Specimen TCGA-EJ-7786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 750e6c0c-d523-4031-bc02-edae4875a64d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7786-10A (Blood Derived Normal), aliquot TCGA-EJ-7786-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e31f3f5-4df2-4358-9a87-c8be88880c01

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE2 | c.617A>T p.N206I | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV59692148; called by muse, mutect2
- AMPD1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV62415255; called by muse, mutect2, varscan2
- APOBEC3B | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.068); catalogued as COSV59840453; called by muse, mutect2, varscan2
- AVPR1B | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 28/626 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65637817; called by muse, mutect2
- BSN | c.8671C>T p.R2891C | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56514027; called by muse, mutect2
- CCKBR | c.65G>C p.C22S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.053); catalogued as COSV58099360; called by muse, mutect2
- FZR1 | c.523C>G p.P175A | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV58050612; called by muse, mutect2
- GLRA2 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV54337085; called by muse, mutect2
- GRIA3 | c.2486A>C p.Y829S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52051391; called by muse, mutect2, varscan2
- ITGB2 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56608408, COSV56610182; called by muse, mutect2, varscan2
- IWS1 | c.1064T>C p.M355T | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV54866884; called by muse, mutect2, varscan2
- LMBRD1 | c.698A>G p.Y233C (on ENST00000649011; = p.Y211C on NM_018368.4) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV65296372; called by muse, mutect2
- MCM3 | c.1837A>C p.M613L (on ENST00000229854 / NM_001366374.2; = p.M603L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57716804; called by muse, mutect2
- MOAP1 | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as COSV52092274; called by muse, mutect2, varscan2
- OR8H2 | c.496T>A p.L166M | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57943594; called by muse, mutect2
- SOHLH1 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV53680863; called by muse, mutect2, varscan2
- CDKN1B | c.374_375dup p.E126Lfs*20 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- NDC1 | c.657A>G p.E219= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV52333800; called by muse, mutect2
- PARD6A | c.21T>C p.T7= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as rs1324034252, COSV54666341; called by muse, mutect2
- STK26 | c.177A>G p.E59= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV61229034; called by muse, mutect2, varscan2
- TGFBI | c.1566C>A p.I522= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV59350278; called by muse, mutect2, varscan2
- USP33 | c.936C>T p.S312= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV62468557; called by muse, mutect2
- ZNF215 | c.1311C>T p.S437= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV53492046; called by muse, mutect2
